Somatic mutation profile of tumor specimen TARGET-20-PATAST-09A (aliquot TARGET-20-PATAST-09A-02D) from TARGET case TARGET-20-PATAST, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.2 years (5,926 days).
Specimen TARGET-20-PATAST-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32cc44b4-840a-4898-b5a7-f466a944488e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATAST-14A (Bone Marrow Normal), aliquot TARGET-20-PATAST-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfd62843-c340-474b-95c6-2f4af4121457

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 27/256 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 21/125 reads (17%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BSN | c.7051C>T p.R2351W | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs370022838; called by muse, mutect2
- GABBR2 | c.1984G>A p.A662T | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs760348361, COSV52300480; called by muse, mutect2, varscan2
- PINK1 | c.1125C>T p.D375= | Splice Region (SNP) | VAF 33/73 reads (45%) | catalogued as rs531300037, COSV58630578; called by muse, mutect2, varscan2
